TCGA case TCGA-V4-A9EY — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/15d19ccc-52b8-41f6-b1c1-2cc55691aed5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 66 years; Year of birth: 1946; Vital status: Alive.

Diagnoses (1)
1. Spindle cell melanoma, NOS: ICD-O-3 morphology code: 8772/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 66.2 years (24,187 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,254 days (6.2 years); Sites of involvement: Eye, Choroid.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 20.
   Pathology details: Consistent pathology review: Yes; Extrascleral extension present: No; Measurement type: Echographic; Spindle cell percent range: >90%; Tumor depth measurement: 10.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -3 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 405 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 761 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 837 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 2,254 days (6.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive; Chromosome arm: p.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 8.

Other clinical attributes
- Eye color: Blue.
- Timepoint category: Initial Diagnosis; Weight: 90 kg; Height: 168 cm; BMI: 31.9.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Melanoma.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
  Slide TCGA-V4-A9EY-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9EY-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9EY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Spindle Cell; Tumor morphology percentage: >90%.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 6p gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 837 days; disease-specific survival: no event (censored), 837 days; progression-free interval: no event (censored), 837 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9EY-01A-11D-A39V-01): tumor purity 0.65, ploidy 2.01, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Gain 6p
- days to followup: 2254
- days to outcome: 2254
- days to procedure 1: -3
- disease status at last followup: No Evidence of Disease
- line of therapy 1: first
- m stage: M0
- morphologic subtype: spindle
- n stage: N0
- outcome: Complete Response
- resection status 1: R0
- staging system: AJCC
- t stage: T4a
- test methodology: aCGH
- test result: low risk
- unresectable 1: no
